Gene-level copy-number profile of tumor specimen TCGA-49-AAQV-01A from TCGA case TCGA-49-AAQV, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage II; Age at diagnosis: 64.0 years (23,370 days).
Specimen TCGA-49-AAQV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.624902a0-f771-4daa-9598-ec7e5cfcc7bd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-49-AAQV-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5fcf24e2-21e5-4f17-8a0c-00ca83962191

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 12,226; copy number 2: 36,623; copy number 3: 7,018; copy number 4: 3,792; copy number 5: 142.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-49-AAQV-01A-11D-A396-01): tumor purity 0.25, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:20,295,089–20,661,583, 14 genes (within-gene range 0–2): AC078899.4, BNIP3P19, AC078899.5, ZNF826P, BNIP3P20, AC078899.2, MIR1270, BNIP3P22, AC008554.1, BNIP3P23, ZNF737, AC010636.2, VN1R78P, AC010636.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 142 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,444,509–181,342,213, 53 genes, copy number 5: RNU6-525P, CNOT6, AC122714.1, SCGB3A1, FLT4, AC122714.2, LINC02222, OR2AI1P, RNU1-17P, OR2Y1, MGAT1, AC022413.1, HEIH, LINC00847, AC022413.2, ZFP62, BTNL8, Y_RNA, RPS29P12, AC091874.2, AC091874.1, ARPP19P1, BTNL3, RNU6-1036P, BTNL9, MIR8089, AC008620.1, FOXO1B, AC008620.2, OR2V1, OR2V2, LINC01962, AC008443.4, TRIM7, TRIM7-AS1, AC008443.3, AC008443.7, TRIM41, MIR4638, AC008443.1, RACK1, SNORD96A, SNORD95, CTC-338M12.4, TRIM52, TRIM52-AS1, AC008443.6, AC008443.2, AC008443.5, RNU6-705P, AC138035.1, AC138035.3, AC138035.2.
- chr12:64,654,060–65,491,430, 20 genes, copy number 5 (within-gene range 2–5): AC078962.3, AC025262.2, AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60.
- chr14:35,121,846–35,317,474, 2 genes, copy number 5 (within-gene range 4–5): PRORP, AL121594.1.
- chr14:35,219,023–38,728,481, 67 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,226. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
